Somatic mutation profile of tumor specimen 0DS06Q from CCDI case PBCFKU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.6 years (204 days).
Specimen 0DS06Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90d35018-51e0-4952-853d-7ac307dfdf23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS06S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11249877-14c1-4636-8e73-3be8d0edcd85

The open-access MAF lists 8 somatic variants for this specimen: 2 protein-altering or splice-affecting, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 4, Missense Mutation 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 67/1030 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ZNF669 | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 38/489 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.001); called by mutect2, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 13/100 reads (13%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 40/242 reads (17%) | called by muse, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 23/532 reads (4%) | called by muse, mutect2
